Somatic mutation profile of tumor specimen MMRF_1719_1_BM_CD138pos (aliquot MMRF_1719_1_BM_CD138pos_T1_KBS5U_K11309) from MMRF case MMRF_1719, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.0 years (24,097 days).
Specimen MMRF_1719_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f415699-9087-4b02-8e3f-3a73437714c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1719_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1719_1_PB_Whole_C2_KBS5U_K11310; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b03858c-b070-46d9-8359-44c73187e98b

The open-access MAF lists 85 somatic variants for this specimen: 34 protein-altering or splice-affecting, 13 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, 3'UTR 18, Silent 13, Intron 11, 5'Flank 3, 3'Flank 3, Frame Shift Ins 2, Splice Region 2, RNA 2, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 154/362 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CAMSAP2 | c.1382G>A p.R461H (on ENST00000236925 / NM_001297707.2; = p.R450H on NM_203459.3) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs759708454, COSV99373580; called by muse, mutect2, varscan2
- EGFR | c.607G>T p.G203* | Nonsense Mutation (SNP) | VAF 26/45 reads (58%) | catalogued as COSV51811244; called by muse, mutect2, varscan2
- GPR20 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775863809; called by muse, mutect2, varscan2
- HGF | c.1866G>A p.L622= | Splice Region (SNP) | VAF 30/64 reads (47%) | catalogued as rs376395424; called by muse, mutect2, varscan2
- IGLV3-25 | c.332G>T p.S111I | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs537761116; called by muse, varscan2
- MYH2 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV55448833; called by muse, mutect2, varscan2
- NCF2 | c.1092G>A p.M364I | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV62316202; called by muse, mutect2, varscan2
- NCOA3 | c.3816_3818del p.Q1276del (on ENST00000371998 / NM_181659.3; = p.Q1272del on NM_006534.4) | In Frame Del (DEL) | VAF 10/49 reads (20%) | catalogued as rs772979098; called by pindel, varscan2
- NFIA | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64537618; called by muse, mutect2, varscan2
- PDZRN4 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs759927473, COSV68414622; called by muse, mutect2, varscan2
- PROKR2 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 79/139 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.317); catalogued as rs576243101, COSV54085395; called by muse, mutect2, varscan2
- SDK2 | c.6262C>T p.R2088W | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs746513867; called by muse, mutect2, varscan2
- SPTBN5 | c.6476C>T p.T2159I | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as COSV100310686; called by muse, mutect2, varscan2
- ZYX | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs772321192; called by muse, mutect2, varscan2
- ASB4 | c.436T>G p.F146V | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- C2CD4B | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- CXCR4 | c.1012dup p.S338Ffs*6 | Frame Shift Ins (INS) | VAF 19/55 reads (35%) | called by mutect2, pindel, varscan2
- FOXF2 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- FSIP2 | c.2440G>A p.D814N | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- GRIK2 | c.248T>A p.I83K | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- H4-16 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- HNRNPL | c.1753G>C p.A585P | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- HNRNPUL1 | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- MYLK | c.755-4C>T | Splice Region (SNP) | VAF 57/124 reads (46%) | called by muse, mutect2, varscan2
- NAT2 | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- NFRKB | c.3124G>T p.V1042F (on ENST00000446488 / NM_001143835.2; = p.V1067F on NM_006165.3) | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- OR13A1 | c.431T>C p.I144T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PARP6 | c.787C>G p.L263V | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PCID2 | c.22C>G p.Q8E | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- TENT5C | c.343_344insG p.S115Cfs*36 | Frame Shift Ins (INS) | VAF 40/105 reads (38%) | called by mutect2, pindel, varscan2
- TENT5C | c.619del p.H207Tfs*4 | Frame Shift Del (DEL) | VAF 49/130 reads (38%) | called by mutect2, pindel, varscan2
- TRPC4 | c.2461T>A p.S821T (on ENST00000379705 / NM_016179.4; = p.S826T on NM_003306.3) | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TXNDC5 | c.964-41_966del p.X322_splice | Splice Site (DEL) | VAF 44/162 reads (27%) | called by mutect2, pindel
- ADAMTS1 | c.273C>T p.P91= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV53171354; called by muse, mutect2, varscan2
- CAND2 | c.2379G>T p.G793= (on ENST00000456430 / NM_001162499.2; = p.G700= on NM_012298.3) | Silent (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- CYP1A1 | c.255G>A p.V85= | Silent (SNP) | VAF 51/208 reads (25%) | called by muse, mutect2, varscan2
- CYP4F3 | c.1233C>A p.G411= | Silent (SNP) | VAF 76/237 reads (32%) | called by muse, mutect2, varscan2
- DNAAF2 | c.252G>C p.G84= | Silent (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- ESPL1 | c.981G>A p.E327= | Silent (SNP) | VAF 105/198 reads (53%) | called by muse, mutect2, varscan2
- GIMAP2 | c.57C>T p.S19= | Silent (SNP) | VAF 41/95 reads (43%) | called by muse, mutect2, varscan2
- HECW1 | c.435C>T p.I145= | Silent (SNP) | VAF 61/129 reads (47%) | catalogued as rs746181473, COSV67836476; called by muse, mutect2, varscan2
- IGHV1-69D | c.352_353insCCCCAAGAAGTATAGAGAG p.*118delinsAPRSIER | Silent (INS) | VAF 6/18 reads (33%) | called by mutect2, pindel
- IGLV3-1 | c.252C>T p.N84= | Silent (SNP) | VAF 82/82 reads (100%) | catalogued as rs181381534; called by muse, varscan2
- RRBP1 | c.2343G>A p.R781= (on ENST00000377813 / NM_001365613.2; = p.R348= on NM_004587.3) | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs1273270055; called by muse, mutect2, varscan2
- SPRR2E | c.63A>G p.P21= | Silent (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- ZNF683 | c.480G>A p.P160= | Silent (SNP) | VAF 46/85 reads (54%) | catalogued as rs765766057, COSV62873215; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501433 G>C | 5'Flank (SNP) | VAF 72/332 reads (22%) | called by muse, varscan2
- APOL6 | c.*1365T>G | 3'UTR (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- ASB8 | c.234+238T>A | Intron (SNP) | VAF 31/77 reads (40%) | catalogued as rs1225943564; called by muse, mutect2, varscan2
- BEND7 | c.1081+803C>G | Intron (SNP) | VAF 31/52 reads (60%) | called by muse, mutect2, varscan2
- BICD2 | c.*646A>G | 3'UTR (SNP) | VAF 85/86 reads (99%) | catalogued as rs919564083; called by muse, mutect2, varscan2
- CHRM2 | chr7:137018203 del A | 3'Flank (DEL) | VAF 47/83 reads (57%) | catalogued as rs922026473; called by mutect2, varscan2
- COL27A1 | c.5108-73G>T | Intron (SNP) | VAF 22/74 reads (30%) | called by muse, varscan2
- CPLANE1 | c.8300-10del | Intron (DEL) | VAF 25/93 reads (27%) | called by mutect2, pindel
- CSMD1 | chr8:2936699 G>A | 3'Flank (SNP) | VAF 96/183 reads (52%) | called by muse, mutect2, varscan2
- DMD | c.2292+1221C>A | Intron (SNP) | VAF 23/23 reads (100%) | called by muse, mutect2, varscan2
- EGFLAM | c.713-2486C>A | Intron (SNP) | VAF 42/72 reads (58%) | called by muse, mutect2, varscan2
- FAM220BP | n.285G>A | RNA (SNP) | VAF 86/89 reads (97%) | catalogued as rs954462216; called by muse, mutect2, varscan2
- FCRL3 | c.*373A>C | 3'UTR (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- FIGN | c.*5976G>T | 3'UTR (SNP) | VAF 45/97 reads (46%) | called by mutect2, varscan2
- GPCPD1 | c.*804C>T | 3'UTR (SNP) | VAF 15/23 reads (65%) | called by muse, mutect2, varscan2
- ISG20 | c.*67T>C | 3'UTR (SNP) | VAF 194/376 reads (52%) | called by muse, mutect2, varscan2
- LINC02228 | n.371T>A | RNA (SNP) | VAF 11/31 reads (35%) | called by muse, varscan2
- LRRIQ3 | c.*287T>C | 3'UTR (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- LTB | c.163-96A>G | Intron (SNP) | VAF 115/241 reads (48%) | catalogued as rs541371875; called by muse, mutect2, varscan2
- NUDCD1 | c.1459+20A>T | Intron (SNP) | VAF 40/68 reads (59%) | called by muse, varscan2
- PDGFRA | c.2156+363C>T | Intron (SNP) | VAF 36/69 reads (52%) | catalogued as rs1312337921; called by muse, mutect2, varscan2
- PELI3 | c.*676G>A | 3'UTR (SNP) | VAF 37/168 reads (22%) | catalogued as rs1424709636; called by muse, mutect2, varscan2
- PIP4K2B | c.*2821T>C | 3'UTR (SNP) | VAF 34/69 reads (49%) | catalogued as rs1289288176; called by muse, mutect2, varscan2
- PLAAT5 | chr11:63462855 T>G | 3'Flank (SNP) | VAF 64/129 reads (50%) | called by muse, mutect2, varscan2
- POLR2D | c.*39C>T | 3'UTR (SNP) | VAF 79/152 reads (52%) | called by muse, mutect2, varscan2
- PTN | c.*538A>C | 3'UTR (SNP) | VAF 22/68 reads (32%) | called by mutect2, varscan2
- RASSF10 | chr11:13009310 del TTGGGCA | 5'UTR (DEL) | VAF 9/24 reads (38%) | called by mutect2, varscan2
- RFTN2 | chr2:197675858 A>G | 5'Flank (SNP) | VAF 40/70 reads (57%) | called by muse, mutect2, varscan2
- RIMS2 | c.*404G>A | 3'UTR (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- SLC25A37 | c.*1692G>A | 3'UTR (SNP) | VAF 50/104 reads (48%) | called by muse, mutect2, varscan2
- SNX13 | c.2627-172G>A | Intron (SNP) | VAF 38/67 reads (57%) | called by muse, mutect2, varscan2
- SOCS1 | c.*47A>T | 3'UTR (SNP) | VAF 97/185 reads (52%) | called by muse, mutect2, varscan2
- SOX8 | c.*798T>C | 3'UTR (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- SRFBP1 | c.*74G>A | 3'UTR (SNP) | VAF 56/138 reads (41%) | called by muse, mutect2, varscan2
- TGIF1 | chr18:3449831 A>C | 5'Flank (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- TNFRSF11A | c.*68C>T | 3'UTR (SNP) | VAF 34/73 reads (47%) | catalogued as rs985374091; called by muse, mutect2, varscan2
- TUB | c.*2902G>T | 3'UTR (SNP) | VAF 47/172 reads (27%) | catalogued as rs1438279231; called by muse, mutect2, varscan2
- VGLL3 | c.937+6424C>T | Intron (SNP) | VAF 34/86 reads (40%) | called by muse, mutect2, varscan2
